Somatic mutation profile of cancer-model specimen HCM-WCMC-0491-C16-85A (3D Organoid, passage 10; aliquot HCM-WCMC-0491-C16-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-WCMC-0491-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.0 years (24,110 days).
Specimen HCM-WCMC-0491-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4620c5ac-21dd-4fb5-b5bc-74e6699d090e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0491-C16-10A (Blood Derived Normal), aliquot HCM-WCMC-0491-C16-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b69682f9-061d-493b-acd7-6785377b350c

The open-access MAF lists 268 somatic variants for this specimen: 203 protein-altering or splice-affecting, 56 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 56, Nonsense Mutation 9, Intron 4, 5'Flank 3, In Frame Del 2, Splice Site 2, Frame Shift Ins 2, Splice Region 2, Nonstop Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLVRA | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 393/827 reads (48%) | catalogued as rs387906595, CM095994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 396/399 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.6043G>A p.E2015K (on ENST00000614293; = p.E1985K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 314/658 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs373443721; called by muse, mutect2, varscan2
- ABCD4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 920/920 reads (100%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); catalogued as rs779381980, COSV53994167; called by muse, varscan2
- AC100868.1 | c.1858C>G p.Q620E | Missense Mutation (SNP) | VAF 201/1076 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.075); catalogued as rs1237542709; called by muse, mutect2, varscan2
- ANKRD11 | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 411/412 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748427842; called by muse, varscan2
- AOC3 | c.2107T>C p.F703L | Missense Mutation (SNP) | VAF 190/406 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1223977860; called by muse, mutect2, varscan2
- BCAT2 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 177/377 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs993016942; called by muse, mutect2, varscan2
- CNGA2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 554/558 reads (99%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as rs969937452, COSV100323332; called by muse, varscan2
- COL4A3 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV67420182; called by muse, mutect2, varscan2
- DISP3 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 204/1406 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.978); catalogued as rs1415519319; called by muse, varscan2
- DNAJA3 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 412/942 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs770589646; called by muse, varscan2
- DSCAML1 | c.1469C>T p.A490V (on ENST00000321322; = p.A430V on NM_020693.4) | Missense Mutation (SNP) | VAF 674/1039 reads (65%) | SIFT tolerated (0.51); PolyPhen benign (0.306); catalogued as rs749440763; called by muse, varscan2
- EBF1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 440/977 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs374891820; called by muse, varscan2
- EXO1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 164/222 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs1425606387; called by muse, varscan2
- FBN1 | c.6458G>A p.C2153Y | Missense Mutation (SNP) | VAF 100/488 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM012601; called by muse, varscan2
- GATA5 | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 127/413 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as rs782291037; called by muse, mutect2, varscan2
- GIMAP5 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 201/944 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1331245095; called by muse, varscan2
- GPR89A | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 110/275 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs782673642; called by muse, mutect2, varscan2
- HHIPL2 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs774697746, COSV58564862, COSV58565498; called by muse, varscan2
- ILDR1 | c.1320G>C p.R440S (on ENST00000344209 / NM_001199799.2; = p.R396S on NM_175924.4) | Missense Mutation (SNP) | VAF 219/991 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV56554634; called by muse, mutect2, varscan2
- ITPR1 | c.6793G>A p.V2265M (on ENST00000354582; = p.V2210M on NM_002222.7) | Missense Mutation (SNP) | VAF 215/499 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.538); catalogued as rs767779223, COSV56987274; called by muse, varscan2
- KANK4 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 444/933 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs749518503, COSV62985471, COSV62986746; called by muse, varscan2
- KRT16 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 222/4226 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56967548; called by muse, mutect2
- KRTAP5-7 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 222/862 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV101273251; called by muse, varscan2
- LRPPRC | c.2800A>C p.N934H | Missense Mutation (SNP) | VAF 211/338 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99580471; called by muse, mutect2, varscan2
- LRRC30 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201234858, COSV67301299; called by mutect2, varscan2
- LRRTM3 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 200/548 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.281); catalogued as COSV63667232; called by muse, varscan2
- MAP2K7 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 424/428 reads (99%) | catalogued as COSV60718714; called by muse, mutect2, varscan2
- MARCO | c.450A>C p.Q150H | Missense Mutation (SNP) | VAF 211/664 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.295); catalogued as COSV100503255; called by muse, mutect2, varscan2
- MEFV | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 441/959 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs104895201, CM084936; called by muse, mutect2, varscan2
- MKNK1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 347/677 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs200310287, COSV57860765; called by muse, mutect2, varscan2
- MSR1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 340/541 reads (63%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as rs1375681509, COSV100027255, COSV50526534; called by muse, varscan2
- NLRC4 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 140/471 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV61592818; called by muse, mutect2, varscan2
- NYAP2 | c.1383T>G p.H461Q | Missense Mutation (SNP) | VAF 184/631 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.625); catalogued as COSV99796065; called by mutect2, varscan2
- OSTN | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs746513224, COSV59140136; called by muse, varscan2
- PAPSS1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs754423801, COSV99491973; called by muse, mutect2, varscan2
- PDZRN3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 240/566 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs762534324, COSV55193713; called by muse, varscan2
- PHLPP1 | c.4104C>G p.F1368L | Missense Mutation (SNP) | VAF 188/434 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV53037647; called by muse, mutect2, varscan2
- PLEKHG3 | c.1087C>T p.R363W (on ENST00000394691; = p.R419W on NM_001308147.2) | Missense Mutation (SNP) | VAF 376/578 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778204710, COSV55979296; called by muse, varscan2
- POU4F3 | c.947A>C p.N316T | Missense Mutation (SNP) | VAF 200/812 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771907556; called by muse, mutect2, varscan2
- PTPRQ | c.2296T>G p.L766V (on ENST00000616559; = p.L724V on NM_001145026.2) | Missense Mutation (SNP) | VAF 262/263 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57038322, COSV57057983; called by muse, varscan2
- PTPRT | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 309/470 reads (66%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.967); catalogued as COSV62036834; called by muse, varscan2
- RB1CC1 | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 71/495 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs751214315, COSV50243401; called by muse, varscan2
- RIPK4 | c.1687G>A p.G563R (on ENST00000352483; = p.G515R on NM_020639.3) | Missense Mutation (SNP) | VAF 498/500 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182590763; called by muse, varscan2
- RYR3 | c.5834C>T p.P1945L | Missense Mutation (SNP) | VAF 236/492 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs375210672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SARDH | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 559/562 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs376636689, COSV100898243; called by muse, varscan2
- SCN1A | c.2361G>C p.M787I (on ENST00000303395 / NM_001202435.3; = p.M776I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV57660739, COSV57680767; called by muse, mutect2, varscan2
- SELENOS | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 510/843 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs774935113; called by muse, mutect2, varscan2
- SEMA6D | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 273/591 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV104412987; called by muse, mutect2, varscan2
- SNTG1 | c.287C>A p.S96* | Nonsense Mutation (SNP) | VAF 134/366 reads (37%) | catalogued as COSV52477174; called by muse, mutect2, varscan2
- SOBP | c.2264A>G p.K755R | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1271270620; called by muse, mutect2, varscan2
- SPANXD | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 238/594 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs141382558, COSV65153097; called by muse, mutect2, varscan2
- SPATA31D1 | c.1720C>T p.H574Y | Missense Mutation (SNP) | VAF 778/784 reads (99%) | SIFT tolerated (0.74); PolyPhen benign (0.159); catalogued as COSV100782598, COSV99049216; called by muse, varscan2
- TCF21 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 310/918 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868283914; called by muse, varscan2
- TGFBR2 | c.1544A>T p.E515V | Missense Mutation (SNP) | VAF 110/542 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.544); catalogued as COSV99846738; called by muse, mutect2, varscan2
- THSD7A | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 398/658 reads (60%) | catalogued as rs777727562, COSV69855816; called by muse, varscan2
- TIGD5 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 646/1788 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1245883980; called by muse, mutect2, varscan2
- TMCO3 | c.638A>C p.N213T | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV64808782; called by muse, varscan2
- TXNRD3 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 322/679 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV73119470; called by muse, mutect2, varscan2
- UHRF1BP1L | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 360/362 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54437580, COSV54441861; called by mutect2, varscan2
- USP17L7 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 258/1728 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1362562578; called by muse, varscan2
- ZC3H11A | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 143/261 reads (55%) | catalogued as COSV59748336; called by muse, mutect2, varscan2
- ZC3H4 | c.2582A>G p.D861G | Missense Mutation (SNP) | VAF 331/673 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765165502; called by muse, varscan2
- AC099489.1 | c.4171C>A p.L1391M | Missense Mutation (SNP) | VAF 359/762 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACHE | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 590/1150 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, varscan2
- ADCK5 | c.1537A>G p.S513G | Missense Mutation (SNP) | VAF 191/910 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADGRB1 | c.2532C>G p.N844K | Missense Mutation (SNP) | VAF 287/812 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AGBL1 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 314/654 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALS2 | c.4961A>G p.E1654G | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ANKS1B | c.2458G>A p.E820K (on ENST00000547776 / NM_152788.4; = p.E46K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 493/496 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- APOBR | c.1769A>T p.E590V (on ENST00000431282; = p.E599V on NM_018690.4) | Missense Mutation (SNP) | VAF 211/793 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- APOBR | c.2612A>T p.K871M (on ENST00000431282; = p.K880M on NM_018690.4) | Missense Mutation (SNP) | VAF 519/1092 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, varscan2
- ARHGAP21 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF19 | c.1841A>C p.K614T | Missense Mutation (SNP) | VAF 242/1054 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, varscan2
- ASPDH | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 406/408 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- BARHL1 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 209/841 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAM | c.473C>A p.T158K | Missense Mutation (SNP) | VAF 668/674 reads (99%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- BRD3 | c.1641C>T p.G547= | Splice Region (SNP) | VAF 260/552 reads (47%) | called by muse, mutect2, varscan2
- C1orf127 | c.2472A>C p.*824Cext*22 | Nonstop Mutation (SNP) | VAF 133/519 reads (26%) | called by muse, mutect2, varscan2
- CD1B | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 181/522 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.212); called by mutect2, varscan2
- CD300LB | c.493T>G p.L165V | Missense Mutation (SNP) | VAF 159/552 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.288); called by muse, varscan2
- CDC23 | c.1635A>C p.E545D | Missense Mutation (SNP) | VAF 113/648 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CDC23 | c.1039C>G p.H347D | Missense Mutation (SNP) | VAF 148/548 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP250 | c.3056T>C p.L1019P | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, varscan2
- CHEK2 | c.1254G>T p.L418F (on ENST00000382580 / NM_001005735.2; = p.L375F on NM_007194.4) | Missense Mutation (SNP) | VAF 290/297 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, varscan2
- CHSY1 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 223/1352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLGN | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CNTNAP5 | c.858C>G p.D286E | Missense Mutation (SNP) | VAF 147/534 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COLGALT1 | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 265/267 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CTNNA2 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, varscan2
- DLX2 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 340/1088 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, varscan2
- DMRT2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 426/428 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, varscan2
- DNAH11 | c.4933C>A p.Q1645K | Missense Mutation (SNP) | VAF 181/476 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DNMT1 | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DPH7 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 359/748 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ECSIT | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 186/421 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB5 | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 192/698 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, varscan2
- EYA4 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, varscan2
- FAM135A | c.874-1G>C p.X292_splice (on ENST00000370479 / NM_001351599.1; = p.X275_splice on NM_020819.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 70/230 reads (30%) | called by muse, varscan2
- FAM184B | c.3167A>G p.K1056R | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT1 | c.8029G>A p.D2677N | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN1 | c.7874C>T p.T2625I | Missense Mutation (SNP) | VAF 360/707 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FKBP11 | c.349T>G p.L117V | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FLG | c.2474C>A p.A825E | Missense Mutation (SNP) | VAF 346/614 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, varscan2
- FZR1 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 402/405 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEN1 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 103/285 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HDAC1 | c.1439A>T p.K480M | Missense Mutation (SNP) | VAF 152/706 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, varscan2
- HEATR1 | c.5395G>A p.A1799T | Missense Mutation (SNP) | VAF 409/600 reads (68%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, varscan2
- HEATR5B | c.4628G>C p.G1543A | Missense Mutation (SNP) | VAF 360/563 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HOXB13 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 150/295 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRG | c.358A>T p.R120* | Nonsense Mutation (SNP) | VAF 112/532 reads (21%) | called by muse, varscan2
- IGDCC3 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 98/458 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- INSR | c.3923A>G p.E1308G | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ISG20L2 | c.1025G>A p.W342* | Nonsense Mutation (SNP) | VAF 290/439 reads (66%) | called by muse, varscan2
- IVL | c.1397A>G p.E466G | Missense Mutation (SNP) | VAF 407/660 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- KAT2A | c.1855A>G p.I619V | Missense Mutation (SNP) | VAF 204/1055 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- KIAA0100 | c.887A>T p.K296M | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KLHDC10 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 164/341 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL28 | c.62T>G p.L21R | Missense Mutation (SNP) | VAF 132/491 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, varscan2
- KRT37 | c.573C>T p.I191= | Splice Region (SNP) | VAF 223/4892 reads (5%) | called by muse, mutect2
- KRT37 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 310/5800 reads (5%) | called by muse, mutect2
- KRTAP9-9 | c.499T>C p.S167P | Missense Mutation (SNP) | VAF 254/5396 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); called by muse, mutect2
- LGR6 | c.1667A>G p.E556G (on ENST00000367278 / NM_001017403.1; = p.E504G on NM_021636.3) | Missense Mutation (SNP) | VAF 111/441 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- LIPM | c.25T>A p.W9R | Missense Mutation (SNP) | VAF 244/380 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LRRC17 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 243/562 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC41 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 304/689 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, varscan2
- MANBA | c.2495A>T p.N832I (on ENST00000642252; = p.N786I on NM_005908.4) | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MAST2 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 172/352 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MDFIC | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- METTL25 | c.848_869del p.G283Efs*26 | Frame Shift Del (DEL) | VAF 164/190 reads (86%) | called by mutect2, pindel, varscan2
- MEX3A | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 183/735 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MYH2 | c.5021A>C p.K1674T | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEUROD2 | c.53T>G p.F18C | Missense Mutation (SNP) | VAF 202/9144 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- NINL | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 136/449 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NLRP6 | c.757A>C p.I253L | Missense Mutation (SNP) | VAF 720/724 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, varscan2
- NOTCH1 | c.1592A>G p.E531G | Missense Mutation (SNP) | VAF 166/722 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); called by mutect2, varscan2
- NT5DC2 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 122/584 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, varscan2
- NUCKS1 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 87/546 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR5B17 | c.604A>C p.S202R | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OR8B2 | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 106/438 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, varscan2
- PALD1 | c.842A>G p.Q281R | Missense Mutation (SNP) | VAF 231/751 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PAX7 | c.1180A>G p.S394G | Missense Mutation (SNP) | VAF 441/445 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA3 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 309/680 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); called by muse, mutect2
- PCSK6 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 176/1076 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, varscan2
- PIK3R3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PKHD1 | c.8954T>C p.V2985A | Missense Mutation (SNP) | VAF 122/183 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLCB2 | c.640A>T p.S214C | Missense Mutation (SNP) | VAF 141/566 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, varscan2
- PNKD | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 150/536 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIP | c.1225G>T p.V409F | Missense Mutation (SNP) | VAF 129/445 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- POU4F3 | c.262T>C p.C88R | Missense Mutation (SNP) | VAF 289/1256 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- PPP2R5D | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 131/491 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRDM9 | c.1831A>T p.R611W | Missense Mutation (SNP) | VAF 322/759 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by mutect2, varscan2
- PREX2 | c.2065T>C p.F689L | Missense Mutation (SNP) | VAF 259/700 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRKCD | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 101/529 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PRMT6 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 504/505 reads (100%) | called by muse, varscan2
- PRR29 | c.337T>G p.L113V | Missense Mutation (SNP) | VAF 266/804 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS53 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 398/768 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, varscan2
- PSD | c.1317C>G p.F439L | Missense Mutation (SNP) | VAF 531/768 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSD3 | c.1820T>G p.L607R | Missense Mutation (SNP) | VAF 214/692 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMD2 | c.1208A>T p.K403M | Missense Mutation (SNP) | VAF 97/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PSME1 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 168/356 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- RAB1A | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, varscan2
- RAB30 | c.590T>G p.L197W | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- REST | c.1202_1203delinsTAC p.K401Ifs*3 | Frame Shift Ins (INS) | VAF 71/191 reads (37%) | called by pindel, varscan2*
- RIC1 | c.3789G>C p.Q1263H | Missense Mutation (SNP) | VAF 227/228 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- RNF165 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 127/281 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ROBO4 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 246/380 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- RTL1 | c.2510T>A p.L837Q | Missense Mutation (SNP) | VAF 190/578 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SEMA6D | c.3142T>A p.L1048I (on ENST00000316364 / NM_153618.2; = p.L986I on NM_020858.2) | Missense Mutation (SNP) | VAF 199/785 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SEPHS2 | c.550A>C p.S184R | Missense Mutation (SNP) | VAF 195/861 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SET | c.462A>T p.K154N (on ENST00000372692 / NM_001374326.1; = p.K141N on NM_003011.4) | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SHROOM3 | c.3611A>T p.E1204V | Missense Mutation (SNP) | VAF 242/512 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, varscan2
- SIRT1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 129/422 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SLC26A11 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 208/749 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC26A9 | c.1418_1420del p.S473del | In Frame Del (DEL) | VAF 114/735 reads (16%) | called by pindel, varscan2
- SLC41A1 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 123/835 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP100 | c.2207A>C p.N736T | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, varscan2
- SP110 | c.276A>T p.E92D | Missense Mutation (SNP) | VAF 260/396 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, varscan2
- STARD9 | c.9991T>G p.S3331A | Missense Mutation (SNP) | VAF 139/720 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRIP2 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 297/612 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT6H | c.2904G>T p.E968D | Missense Mutation (SNP) | VAF 370/370 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, varscan2
- SYNE2 | c.11462G>T p.S3821I | Missense Mutation (SNP) | VAF 221/389 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, varscan2
- SYNGAP1 | c.4029C>A p.H1343Q | Missense Mutation (SNP) | VAF 175/293 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TBC1D23 | c.477-1G>A p.X159_splice | Splice Site (SNP) | VAF 135/280 reads (48%) | called by muse, mutect2, varscan2
- TBRG4 | c.1818A>C p.E606D | Missense Mutation (SNP) | VAF 279/581 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TCHH | c.925_966del p.K309_R322del | In Frame Del (DEL) | VAF 35/264 reads (13%) | called by pindel, varscan2*
- TENM3 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 146/303 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TG | c.2353T>C p.Y785H | Missense Mutation (SNP) | VAF 337/821 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- THBS2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 218/672 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIGAR | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 352/608 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TLR6 | c.751T>A p.L251I | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TMED3 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 131/614 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TNKS2 | c.2044C>G p.P682A | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, varscan2
- TRAM2 | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 165/490 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TSHZ3 | c.2632A>G p.T878A | Missense Mutation (SNP) | VAF 374/380 reads (98%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- UNC5D | c.1676dup p.N559Kfs*29 | Frame Shift Ins (INS) | VAF 134/382 reads (35%) | called by mutect2, pindel, varscan2
- WDR33 | c.1199A>T p.K400I | Missense Mutation (SNP) | VAF 145/246 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WHAMM | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 120/600 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.124); called by muse, varscan2
- XIRP2 | c.631A>G p.T211A (on ENST00000628543; = p.T386A on NM_152381.6) | Missense Mutation (SNP) | VAF 283/290 reads (98%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, varscan2
- ZNF117 | c.475C>G p.H159D | Missense Mutation (SNP) | VAF 206/435 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ZNF778 | c.1136G>T p.C379F | Missense Mutation (SNP) | VAF 304/306 reads (99%) | SIFT tolerated (0.67); PolyPhen benign (0.052); called by muse, varscan2
- ZNF837 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 266/578 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ADAMTS9 | c.4635G>A p.S1545= | Silent (SNP) | VAF 385/772 reads (50%) | catalogued as rs745869372, COSV55778765; called by muse, varscan2
- ADAMTSL3 | c.3657C>G p.T1219= | Silent (SNP) | VAF 274/582 reads (47%) | called by muse, varscan2
- AMER2 | c.102C>T p.A34= | Silent (SNP) | VAF 496/1176 reads (42%) | called by muse, varscan2
- ARHGEF4 | c.1581G>A p.Q527= | Silent (SNP) | VAF 200/358 reads (56%) | called by muse, varscan2
- AUTS2 | c.84C>A p.G28= | Silent (SNP) | VAF 580/842 reads (69%) | called by muse, mutect2, varscan2
- BEGAIN | c.1065G>A p.A355= | Silent (SNP) | VAF 570/916 reads (62%) | catalogued as rs1329086186; called by muse, varscan2
- BTNL2 | c.1086T>G p.G362= | Silent (SNP) | VAF 108/348 reads (31%) | called by muse, varscan2
- CACNG1 | c.270G>A p.E90= | Silent (SNP) | VAF 288/459 reads (63%) | called by muse, mutect2, varscan2
- CASC3 | c.714T>C p.A238= | Silent (SNP) | VAF 336/5734 reads (6%) | called by muse, mutect2
- CDC23 | c.1038G>A p.Q346= | Silent (SNP) | VAF 148/536 reads (28%) | called by muse, mutect2, varscan2
- CDKAL1 | c.825G>T p.L275= | Silent (SNP) | VAF 316/317 reads (100%) | called by muse, mutect2, varscan2
- CFAP47 | c.4842T>A p.S1614= | Silent (SNP) | VAF 198/198 reads (100%) | called by muse, varscan2
- CHST8 | c.57G>A p.L19= | Silent (SNP) | VAF 50/377 reads (13%) | called by muse, mutect2, varscan2
- CLTCL1 | c.3408T>G p.S1136= | Silent (SNP) | VAF 135/280 reads (48%) | called by muse, mutect2, varscan2
- DCC | c.1992G>A p.K664= | Silent (SNP) | VAF 98/274 reads (36%) | catalogued as COSV59095212; called by muse, varscan2
- DLGAP2 | c.873C>T p.P291= | Silent (SNP) | VAF 400/2440 reads (16%) | catalogued as rs375164454; called by muse, varscan2
- E2F6 | c.822A>G p.E274= | Silent (SNP) | VAF 612/626 reads (98%) | called by muse, mutect2, varscan2
- FLG | c.2475A>C p.A825= | Silent (SNP) | VAF 348/612 reads (57%) | called by muse, varscan2
- FOXF1 | c.450G>C p.A150= | Silent (SNP) | VAF 469/470 reads (100%) | called by muse, mutect2, varscan2
- GARRE1 | c.1992C>A p.G664= | Silent (SNP) | VAF 313/313 reads (100%) | called by muse, mutect2, varscan2
- HEATR6 | c.1686A>G p.K562= | Silent (SNP) | VAF 101/346 reads (29%) | catalogued as COSV51745989; called by muse, mutect2, varscan2
- HMX1 | c.414T>C p.P138= | Silent (SNP) | VAF 160/849 reads (19%) | called by muse, varscan2
- HSPA4L | c.654A>G p.G218= | Silent (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- IDO2 | c.453C>T p.N151= (on ENST00000389060; = p.N164= on NM_194294.2) | Silent (SNP) | VAF 221/577 reads (38%) | called by muse, mutect2, varscan2
- ISOC1 | c.300G>A p.L100= | Silent (SNP) | VAF 94/502 reads (19%) | called by muse, varscan2
- KANK2 | c.816A>T p.R272= | Silent (SNP) | VAF 214/484 reads (44%) | called by muse, varscan2
- KAT6A | c.2283G>A p.Q761= | Silent (SNP) | VAF 224/653 reads (34%) | called by muse, mutect2, varscan2
- LHCGR | c.954T>C p.S318= | Silent (SNP) | VAF 145/148 reads (98%) | called by muse, mutect2, varscan2
- LINGO1 | c.754T>C p.L252= | Silent (SNP) | VAF 160/716 reads (22%) | catalogued as rs1338907393; called by muse, mutect2, varscan2
- MALRD1 | c.5445C>T p.Y1815= | Silent (SNP) | VAF 236/369 reads (64%) | called by muse, varscan2
- MAPK11 | c.180G>A p.Q60= | Silent (SNP) | VAF 442/445 reads (99%) | called by muse, mutect2, varscan2
- MYADML2 | c.699G>T p.V233= | Silent (SNP) | VAF 401/630 reads (64%) | called by muse, mutect2, varscan2
- OCRL | c.2586T>G p.T862= | Silent (SNP) | VAF 149/275 reads (54%) | called by muse, mutect2, varscan2
- OR4C12 | c.84A>G p.V28= | Silent (SNP) | VAF 253/400 reads (63%) | called by muse, varscan2
- OR4D5 | c.381C>G p.S127= | Silent (SNP) | VAF 189/613 reads (31%) | called by muse, mutect2, varscan2
- OSBPL3 | c.606T>A p.S202= | Silent (SNP) | VAF 230/550 reads (42%) | catalogued as COSV57655481; called by muse, varscan2
- P2RY8 | c.834G>C p.T278= | Silent (SNP) | VAF 517/1134 reads (46%) | catalogued as rs1242981270; called by muse, mutect2, varscan2
- PIGO | c.2370A>G p.Q790= | Silent (SNP) | VAF 166/392 reads (42%) | catalogued as rs1371463681; called by muse, varscan2
- PTPN23 | c.3393T>C p.T1131= | Silent (SNP) | VAF 632/1444 reads (44%) | called by muse, varscan2
- PUM2 | c.3153G>C p.P1051= | Silent (SNP) | VAF 92/594 reads (15%) | catalogued as COSV100164019; called by muse, varscan2
- PXDN | c.3336C>T p.G1112= | Silent (SNP) | VAF 431/1204 reads (36%) | catalogued as rs372885613; called by muse, varscan2
- SBF1 | c.3009C>T p.S1003= | Silent (SNP) | VAF 437/439 reads (100%) | catalogued as rs752939799; called by muse, varscan2
- SEPHS1 | c.1074G>A p.E358= | Silent (SNP) | VAF 163/520 reads (31%) | called by muse, mutect2, varscan2
- SERPINI2 | c.111T>A p.V37= | Silent (SNP) | VAF 268/560 reads (48%) | called by muse, varscan2
- SLC22A8 | c.642C>T p.L214= | Silent (SNP) | VAF 212/697 reads (30%) | catalogued as rs768414272; called by muse, mutect2, varscan2
- SLC25A12 | c.2019A>G p.A673= | Silent (SNP) | VAF 75/263 reads (29%) | called by muse, mutect2, varscan2
- SLC6A12 | c.930G>A p.K310= | Silent (SNP) | VAF 338/341 reads (99%) | called by muse, mutect2, varscan2
- SOX11 | c.1077C>T p.D359= | Silent (SNP) | VAF 221/1295 reads (17%) | catalogued as rs777205305; called by muse, mutect2, varscan2
- SPATA24 | c.588C>T p.A196= | Silent (SNP) | VAF 250/520 reads (48%) | catalogued as rs573494886; called by muse, mutect2, varscan2
- TNN | c.2601C>G p.A867= | Silent (SNP) | VAF 187/598 reads (31%) | called by muse, mutect2, varscan2
- TNS1 | c.3369C>A p.P1123= | Silent (SNP) | VAF 244/853 reads (29%) | called by muse, varscan2
- UBE2L5 | c.195A>G p.P65= | Silent (SNP) | VAF 345/764 reads (45%) | called by muse, mutect2, varscan2
- USH2A | c.4956G>A p.P1652= | Silent (SNP) | VAF 85/364 reads (23%) | catalogued as rs201924343; called by muse, mutect2, varscan2
- VPS35L | c.1473A>G p.K491= | Silent (SNP) | VAF 114/476 reads (24%) | called by muse, mutect2, varscan2
- ZNF205 | c.1353C>T p.P451= | Silent (SNP) | VAF 590/1278 reads (46%) | catalogued as rs368319158; called by muse, varscan2
- ZNF565 | c.207C>T p.D69= (on ENST00000355114; = p.D29= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 312/313 reads (100%) | catalogued as rs1163752027; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825451 C>A | 5'Flank (SNP) | VAF 208/208 reads (100%) | called by muse, varscan2
- CNST | c.-168_-131del | 5'UTR (DEL) | VAF 244/450 reads (54%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2461+2697G>A | Intron (SNP) | VAF 404/406 reads (100%) | catalogued as rs746936420, COSV100154534; called by muse, mutect2, varscan2
- DTHD1 | chr4:36281794 C>A | 5'Flank (SNP) | VAF 114/266 reads (43%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-10453A>T | Intron (SNP) | VAF 272/275 reads (99%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3012-6096A>C | Intron (SNP) | VAF 131/681 reads (19%) | called by muse, mutect2, varscan2
- MLIP | c.64-9958G>T | Intron (SNP) | VAF 99/285 reads (35%) | called by mutect2, varscan2
- SYT15 | chr10:46578874 A>T | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- TM9SF3 | c.*1322T>C | 3'UTR (SNP) | VAF 112/405 reads (28%) | called by muse, varscan2
